Surgical pathology report (de-identified scan), TCGA case TCGA-2F-A9KR, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Erasmus MC, specimen TCGA-2F-A9KR-01A (Primary Tumor).

Pathology report

ICD-O-3
Carcinoma, urothelial
papillary 8130/3
Site: Bladder NOS C67.9
QW 1/29/14

Date of tumor procurement

Date of report

Histologic diagnosis

High grade papillary muscle invasive urothelial cell carcinoma. T3G3 N0

Anatomic site and laterality

Bladder NOS

Tumor size

4cm diameter

Lymph node status

No lymph node metastasis were found.

QW 12/10/13

Source: NCI Genomic Data Commons file 18d88e27-6b53-45a8-a651-e93756f30089 (TCGA-2F-A9KR.EC17D988-194A-4C20-9BF8-D7CC75D9DF55.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).